Somatic mutation profile of tumor specimen TCGA-61-2088-01A (aliquot TCGA-61-2088-01A-01W-0722-08) from TCGA case TCGA-61-2088, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.4 years (18,770 days).
Specimen TCGA-61-2088-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ad087916-e2f7-49bf-ae83-b947d0b7379c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2088-11A (Solid Tissue Normal), aliquot TCGA-61-2088-11A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38e50b58-d5b5-42c9-bd91-64e20459c14d

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Splice Site 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K1 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 49/105 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1287268127, COSV68121509, COSV68122713; called by muse, mutect2, varscan2
- TP53 | c.710_718del p.M237_N239del | In Frame Del (DEL) | VAF 150/180 reads (83%) | hotspot (GDC flag); called by mutect2, varscan2
- ANKRD13B | c.836C>G p.S279C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV61472114; called by muse, mutect2, varscan2
- COL11A2 | c.2506C>T p.P836S (on ENST00000341947 / NM_080680.3; = p.P729S on NM_080679.2) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV59502878; called by muse, mutect2, varscan2
- FARSA | c.552C>A p.S184R | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV58906101, COSV58906210; called by muse, mutect2, varscan2
- GPR132 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.876); catalogued as rs569054802, COSV61678093; called by muse, mutect2, varscan2
- HERC2 | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 8/243 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1271703222, COSV99873521; called by muse, mutect2
- HSPG2 | c.97T>C p.S33P | Missense Mutation (SNP) | VAF 154/311 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.092); catalogued as COSV65977577; called by muse, mutect2, varscan2
- LRP1B | c.10102C>T p.L3368F | Missense Mutation (SNP) | VAF 63/298 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as rs761544976, COSV67277448; called by muse, mutect2, varscan2
- MED12L | c.5298G>T p.K1766N | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV56391802, COSV56398609; called by muse, mutect2, varscan2
- PIGA | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61238517; called by muse, mutect2, varscan2
- TRMT44 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs576421639, COSV67663840; called by muse, mutect2, varscan2
- USP21 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs768795185, COSV57091391; called by muse, mutect2, varscan2
- ZNF140 | c.10-2A>C p.X4_splice | Splice Site (SNP) | VAF 159/286 reads (56%) | catalogued as COSV60580108; called by muse, mutect2, varscan2
- CMTM7 | c.515-8_519del p.X172_splice | Splice Site (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- SEC23B | c.12_15del p.Y4* | Frame Shift Del (DEL) | VAF 15/22 reads (68%) | called by pindel*, varscan2
- KRT17 | c.597G>A p.L199= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as rs548588155, COSV100245127; called by muse, mutect2, varscan2
- RERG | c.534G>A p.R178= | Silent (SNP) | VAF 210/577 reads (36%) | catalogued as COSV57005464; called by muse, mutect2, varscan2
- RTP3 | c.352C>T p.L118= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV56124479; called by muse, mutect2, varscan2
- SUPT6H | c.1266T>G p.A422= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as COSV58931663; called by muse, mutect2, varscan2
- WNT2 | c.507C>T p.R169= | Silent (SNP) | VAF 73/155 reads (47%) | catalogued as rs370359868; called by muse, mutect2, varscan2
